CCDI case PBBUBT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/8108af75-d685-45f1-9425-e14b7c09374e

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 0.6 years (209 days).

Biospecimens (3 samples)
- Sample 0DHBCV: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DHBD5: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DHBD6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
